TCGA case TCGA-DQ-5625 — Head and Neck Squamous Cell Carcinoma (TCGA-HNSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Other and unspecified parts of tongue; Tissue source site: University Of Michigan. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/53d9a130-4a3a-4491-85cd-9a44415a1632

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 52 years; Vital status: Dead; Days to death: 1,133 days (3.1 years); Cause of death: Not Cancer Related.

Diagnoses (3)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C02.9; Tissue or organ of origin: Tongue, NOS; Site of resection or biopsy: Head, face or neck, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 52.6 years (19,211 days); Year of diagnosis: 2008; AJCC staging edition: 6th; AJCC clinical T: T2; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage II; AJCC pathologic T: TX; AJCC pathologic N: NX; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,133 days (3.1 years).
   Pathology details: Consistent pathology review: Yes; Extranodal extension: No Extranodal Extension; Lymph nodes positive: 0; Lymph nodes tested: 19; Lymphatic invasion present: No; Margin status: Uninvolved; Perineural invasion present: No; Vascular invasion present: No.
   Pathology details: Lymph node dissection method: Functional (Limited) Neck Dissection; Lymph node dissection site: Neck, Right.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: Cure; Days to treatment end: 0 days; Treatment outcome: No Measurable Disease.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Squamous cell carcinoma, NOS), site: Floor of mouth, NOS. Age at diagnosis: 55.5 years (20,269 days); Days to diagnosis: 1,058 days (2.9 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 1,067 days (2.9 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease.
3. Recurrence of diagnosis 1 (Squamous cell carcinoma, NOS), site: Mouth, NOS. Age at diagnosis: 55.5 years (20,269 days); Days to diagnosis: 1,058 days (2.9 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 1,067 days (2.9 years); Treatment anatomic sites: Locoregional Site.

Follow-up (4 entries)
- Day 1,058 (post initial treatment): Disease response: With Tumor; Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Mouth, NOS; Days to recurrence: 1,058 days (2.9 years).
- Day 1,058 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Floor of mouth, NOS; Days to recurrence: 1,058 days (2.9 years); Evidence of recurrence type: Biopsy with Histologic Confirmation.
- Days to follow up: 1,133 days (3.1 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day 1,081.

Exposures
- Alcohol history: Yes; Alcohol drinks per day: 15; Alcohol days per week: 7.
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 33; Tobacco smoking onset year: 1975.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DQ-5625-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.7; Intermediate dimension: 0.5; Shortest dimension: 0.2.
  Slide TCGA-DQ-5625-01A-01-TS1: Section location: Top; Percent tumor cells: 55; Percent tumor nuclei: 80; Percent normal cells: 40; Percent necrosis: 0; Percent stromal cells: 5.
  Slide TCGA-DQ-5625-01A-01-BS1: Section location: Bottom; Percent tumor cells: 60; Percent tumor nuclei: 80; Percent normal cells: 35; Percent necrosis: 0; Percent stromal cells: 5.
- Sample TCGA-DQ-5625-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DQ-5625-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Head and Neck; Histologic diagnosis: Head & Neck Squamous Cell Carcinoma; Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Anatomic organ subdivision: Oral Tongue; Lymph nodes examined: Yes; Lymph node neck dissection indicator: Yes; Margin status: Negative; Lymphovascular invasion: No; Tobacco smoking history indicator: 2; Alcohol consumption frequency: 7.
- Follow-up form 1: New tumor event surgery: Yes; New tumor event site: Oral Cavity; Treatment outcome first course: Complete Remission/Response.
- Follow-up form 2: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; Tobacco smokeless use at diagnosis: No; Tobacco smokeless regular use: No; Definitive treatment method: Surgery; Definitive treatment evidence disease after: No; Cause of death: Other, non-malignant disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,133 days; disease-specific survival: no event (censored), 1,133 days; disease-free interval: event (new tumor event after initially disease-free), 1,058 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,058 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DQ-5625-01A-01D-1869-01): tumor purity 0.46, ploidy 2.47, whole-genome doublings 0.
